Somatic mutation profile of tumor specimen TARGET-20-PASPSV-09A (aliquot TARGET-20-PASPSV-09A-02D) from TARGET case TARGET-20-PASPSV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.0 years (4,757 days).
Specimen TARGET-20-PASPSV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b7503a6-3140-411f-8b20-6007c433e80e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASPSV-14A (Bone Marrow Normal), aliquot TARGET-20-PASPSV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecfa20df-a1e8-43c8-b1ac-67250b4b2bb4

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4873C>A p.R1625S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57429702; called by muse, mutect2
- SETD2 | c.4586+1G>C p.X1529_splice | Splice Site (SNP) | VAF 36/114 reads (32%) | catalogued as COSV57456700; called by muse, mutect2, varscan2
- SRCAP | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52674177; called by muse, mutect2
